CCDI case PBCHVW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/16581f5a-f4f8-4aa4-95e7-4e331ff6cb72

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Retinoblastoma, NOS: ICD-O-3 morphology code: 9510/3; Tissue or organ of origin: Retina; Age at diagnosis: 2.9 years (1,074 days).

Biospecimens (3 samples)
- Sample 0DSKZH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSKZN: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSL0D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
